Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8MU, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8MU-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name
Med. Rec. #:
DOB:
Soc. Sec. #:
Physician(s):

Visit #:
Sex: Male
Location:

Accession #:
Service Date:
Received:
Client:

ICD-O-3

FINAL PATHOLOGIC DIAGNOSIS

*Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
2013/1/14*

- A. Prostate, right posterior base, biopsy: Vascular fibroadipose tissue, smooth muscle and nerve. No tumor.
- B. Prostate, left posterior apex margin, biopsy: Prostatic adenocarcinoma; see comment.
- C. Lymph nodes, right external iliac, dissection: No tumor in two lymph nodes (0/2).
- D. Lymph nodes, right obturator, dissection: Metastatic adenocarcinoma in one of three lymph nodes (1/3).
- E. Lymph nodes, left external iliac, dissection: No tumor in five lymph nodes (0/5).
- F. Lymph nodes, left obturator, dissection: No tumor in ten lymph nodes (0/10).
- G. Prostate, anterior apical margin, biopsy: Fibromuscular tissue and nerve, no tumor.
- H. Prostate, posterior apex margin, biopsy: Vascular fibromuscular tissue and nerve, no tumor.
- I. Soft tissue, preprostatic, excision: Vascular fibroadipose tissue, no tumor.
- J. Prostate and seminal vesicles, radical prostatectomy:
1. Prostatic adenocarcinoma, Gleason pattern 3+4=7, involving bilateral prostate with limited extracapsular extension; see comment.
2. Seminal vesicles with no tumor.

[page 2 of 5]
COMMENT:

The left posterior apical margin specimen submitted for frozen section (part B) contains a focus of glandular epithelium with complex architecture, but without an infiltrative appearance. Immunohistochemical stains for p63 and HMWK were obtained on this specimen and the focus in question is negative for basal cells. These results support our interpretation that this focus represents prostatic adenocarcinoma.

In addition, cauterized glands highly suspicious for adenocarcinoma are present at the inked, cauterized apical margin of the main specimen (slides J1 and J2). Immunohistochemical stains for p63 and HMWK were obtained on block J2 in order to evaluate these glands. The glands in question are negative for basal cells, supporting the interpretation of these foci as adenocarcinoma and our interpretation that this represents tumor at the inked, cauterized margin. Of note, the separately submitted anterior apical margin (part G) and posterior apical margin (part H) are negative for carcinoma. Correlation with operative findings is required in order to determine the final margin status.

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior apex, slides J2 and J9; mid gland, slide J10; base, slide J11; left anterior apex, slides J2 and J12; mid gland, slide J13; base, slide J19; right posterior apex, slides J1 and J6; mid gland, slide J7; base, slide J8; right anterior apex, slides J1 and J3; mid gland, slide J4; base, slide J18.
- **Estimated volume of tumor:** 7.35 cm³.
- **Gleason score:** 3+4; primary pattern 3, secondary pattern 4.
- **Estimated volume > Gleason pattern 3:** 40%.
- **Involvement of capsule:** Tumor invades capsule (slide J7 - right posterior mid gland, slide J8 - right posterior base).
- **Extraprostatic extension:** Present, limited in extent (slide J18 - right posterior base).
has reviewed this section and agrees with the interpretation of limited extraprostatic extension.
- **Margin status for tumor:**
- Positive (slide J1 - right apex, slide J2 - left apex); location and length of largest positive margin: Left apex, slide J2, 1 mm in length. Gleason pattern at largest positive margin: 3 + 4. The separately submitted anterior apical and posterior apical margins (parts G and H) are negative for tumor.

In addition, tumor is present immediately adjacent to the inked margin at the right posterior mid gland (slide J7) and adjacent to the right seminal vesicle (slide J18).

- **Margin status for benign prostate glands:**
- No benign glands present at inked excision margins.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present, focally.
- **Tumor involvement of seminal vesicle:** None.
- **Perineural infiltration:** Present.
- **Lymph node status:**
- Positive;
- Total number of positive nodes: 1.
- Total number of nodes examined: 20.
- Size of largest metastasis in node: 0.3 mm
- Extranodal extension: None.
- **AJCC/UICC stage:** pT3aN1.

Specimen(s) Received

A: Right posterior base (FS)
B: Left posterior apex margin (FS)
C: Right external iliac LN

[page 3 of 5]
D: Right obturator lymph nodes
E: Left external iliac LN
F: Left obturator LN
G: Anterior apical margin
H: Posterior apex margin
I: Pre-prostate fat
J: Prostate & seminal vesicles (fresh)

Intraoperative Diagnosis

FS1 (A) Right posterior base, biopsy: Benign vascular fibroadipose tissue, smooth muscle, and nerve, no epithelium, no tumor.

FS2 (B) Left posterior apex margin, biopsy: Glands with smooth muscle, highly suspicious for carcinoma, but cannot entirely rule out benign prostate or peri-urethral glands.

Clinical History

The patient is a _____ man. Review of electronic medical records _____ indicates that the patient has biopsy-proven prostatic adenocarcinoma, Gleason grade 3+4 in the right mid-gland, right base, left apex, left mid-gland and left base _____. The patient now undergoes a robotic assisted laparoscopic radical prostatectomy.

Gross Description

The specimen is received in ten parts, each labeled with the patient's name and medical record number. Parts A, B, and J are received fresh. The remainder of the parts are received in formalin.

Part A, additionally labeled "right posterior base - frozen section," consists of an irregular, unoriented, red-tan soft tissue fragment (1 x 0.3 x 0.2 cm). The entire specimen is frozen for frozen section diagnosis 1, and subsequently submitted in cassette A1.

Part B, additionally labeled "left posterior apex margin - FS," consists of a piece of irregular, unoriented, red-tan soft tissue (0.8 x 0.6 x 0.2 cm). The entire specimen is frozen for frozen section diagnosis 2, and subsequently submitted in cassette B1.

Part C, additionally labeled "right external iliac lymph nodes," consists of a single irregular, unoriented, yellow-tan fibrofatty tissue fragment (4.5 x 2.5 x 0.7 cm). Examination reveals two ovoid, firm, light-tan lymph node candidates (both approximately 1.3 cm) which are bisected and entirely submitted in cassette C1.

Part D, additionally labeled "right obturator lymph nodes," consists of multiple soft to firm, irregular, yellow-tan, fibrofatty tissue fragments (4 x 3 x 1 cm in aggregate). Examination reveals three firm, irregular, light-tan lymph node candidates (1.3 cm - 1.7 cm) which are submitted as follows:

D1: One lymph node candidate, bisected.
D2: One lymph node candidate, bisected.
D3: One lymph node candidate, bisected.

Part E, additionally labeled "left external iliac lymph node," consists of multiple soft to firm, irregular, yellow-tan fibrofatty tissue fragments (3.5 x 3 x 1 cm in aggregate). Examination reveals four firm, light-tan lymph node candidates (0.5 cm - 1.7 cm), which are submitted as follows:

E1: One lymph node candidate, bisected.
E2: One lymph node candidate, bisected.
E3: Two lymph node candidates, intact.

Part F, additionally labeled "left obturator lymph nodes," consists of multiple soft to firm, irregular, yellow-tan fibrofatty tissue fragments (4 x 4 x 1 cm in aggregate). Careful examination reveals eight irregular, firm, tan, unoriented lymph node candidates (0.4 cm - 1.7 cm), which are submitted as follows:

[page 4 of 5]
- F1: One lymph node candidate, bisected.
F2: One lymph node candidate, bisected.
F3: One lymph node candidate, intact.
F4: Two lymph node candidates, intact.
F5: Three lymph node candidates, intact.

Part G, additionally labeled "anterior apical margin," consists of a single, irregularly shaped, unoriented, white-tan, heavily cauterized tissue fragment (0.5 x 0.2 x 0.2 cm). The specimen is inked black and entirely submitted in cassette G1. ()

Part H, additionally labeled "posterior apex margin," consists of three irregular, unoriented, white-tan, cauterized tissue fragments (1 x 0.3 x 0.2 cm in aggregate). The fragments are inked black and entirely submitted in cassette H1.

Part I, additionally labeled "preprostatic fat," consists of a single irregular segment of soft, yellow-tan fibrofatty tissue (3 x 2 x 0.5 cm). Examination reveals no lymph node candidates. The entire specimen is submitted in cassette I1.

Part J, additionally labeled "prostate and bilateral seminal vesicles," consists of a single intact radical prostatectomy specimen with attached seminal vesicle/vas deferens bundles (53.5 gm; 3.8 cm from apex to base x 4.5 cm in width x 3.6 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: There is a large, irregular, poorly defined, lobular, white-tan mass (2 x 1.5 x 0.8 cm) in the right posterior mid gland through base (slices 5-7, cassettes J7 and J8). A second solid, white, well-circumscribed, ovoid nodule (0.7 x 0.7 x 0.7 cm) is noted in the left posterior apex through mid gland (slices 3-5, cassettes J9 and J10). The remaining parenchyma is light-tan and unremarkable. The central-transitional zone is of normal size and composed predominantly of striated, fibrous tissue. No other discrete masses or lesions are noted. The anterior fibrous stroma is open, and the remaining capsule is intact. The seminal vesicle/vas deferens bundles (both measure approximately 5 x 3 x 1 cm) are soft, red-tan, whorled without discrete lesion or mass.

ORIENTED BY: Anatomic landmarks.

INKING:

- Right anterior: Green.
- Left anterior: Blue.
- Posterior: Black.

POTENTIAL STUDIES: Fresh tissue is snap frozen for research purposes.

GROSS PHOTOGRAPHS: Yes.

NUMBER OF SLICES: 9 (inclusive of apical margin) with average slice thickness being 0.42 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margin, entirely submitted in perpendicular sections

J1: Right apex.

J2: Left apex.

Right anterior quadrant

J3: Serial slice 3.

J4: Serial slice 5.

J5: Serial slice 7.

Right posterior quadrant

J6: Serial slice 3.

J7: Serial slice 5.

J8: Serial slice 7.

Left posterior quadrant

J9: Serial slice 3.

J10: Serial slice 5.

J11: Serial slice 7.

Left anterior quadrant

J12: Serial slice 3.

[page 5 of 5]
J13: Serial slice 5.
J14: Serial slice 7.
Bladder margin, entirely submitted in perpendicular sections
J15-J17: Sequentially submitted from right to left.
Prostatic/seminal vesicle junction and cross-section of vas deferens
J18: Right.
J19: Left.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the . They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out

Criteria:	1/31/14	Yes	No

Source: NCI Genomic Data Commons file ce301250-6e1b-42a1-85a5-61ec653de712 (TCGA-V1-A8MU.8E072738-2D8E-4254-B1DE-A8008C614B7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).